Somatic mutation profile of tumor specimen MMRF_1627_3_BM_CD138pos (aliquot MMRF_1627_3_BM_CD138pos_T1_KHS5U_L12907) from MMRF case MMRF_1627, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.0 years (29,968 days).
Specimen MMRF_1627_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98a277e5-b27e-47d5-9705-86266e7290bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1627_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1627_1_PB_Whole_C3_KBS5U_L04316; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5935276c-0c63-4828-9425-671fc508724f

The open-access MAF lists 121 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 35, Intron 17, Silent 12, 5'Flank 6, 5'UTR 5, Splice Site 2, 3'Flank 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.266+1G>A p.X89_splice | Splice Site (SNP) | VAF 69/158 reads (44%) | catalogued as rs1200741849, COSV59379534, COSV59381007; called by muse, mutect2, varscan2
- CDHR5 | c.2224G>A p.A742T (on ENST00000358353 / NM_001171968.2; = p.A748T on NM_021924.5) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs777311849; called by muse, mutect2
- DUOX1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757808802, COSV58487385; called by muse, varscan2
- FSTL5 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV60203532; called by muse, mutect2, varscan2
- HNRNPA3 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV66820987; called by muse, mutect2
- IGHV2-70 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs747883300; called by muse, varscan2
- IGLV3-22 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 154/327 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs756020206; called by muse, mutect2, varscan2
- IGLV3-25 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs145801212; called by muse, varscan2
- ING1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167057; called by muse, mutect2, varscan2
- REEP4 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs763817191; called by muse, mutect2, varscan2
- REV3L | c.8212A>C p.N2738H | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1448911997; called by muse, mutect2, varscan2
- SCARA5 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1008506987; called by muse, mutect2, varscan2
- SCN11A | c.5356G>A p.G1786S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.276); catalogued as rs1450725387; called by muse, mutect2, varscan2
- SCN9A | c.5579G>A p.R1860H (on ENST00000303354; = p.R1849H on NM_002977.3) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs766124857, COSV100312733; called by muse, mutect2, varscan2
- SYNPO2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs951901344; called by muse, mutect2, varscan2
- TSPO | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs961030979; called by muse, mutect2, varscan2
- ARMC5 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- BRS3 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 108/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CABP5 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CD109 | c.142del p.L48Ffs*9 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- CD22 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- CHKB | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 84/93 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAH14 | c.6247G>C p.D2083H (on ENST00000445597; = p.D2736H on NM_001367479.1) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK4 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DZIP1 | c.1786G>T p.E596* (on ENST00000347108; = p.E577* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- FAM20B | c.1141A>C p.S381R | Missense Mutation (SNP) | VAF 144/538 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KBTBD13 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- LARP4B | c.1898G>T p.C633F | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MCTP1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSLN | c.1077C>T p.L359= | Splice Region (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- NFKBIA | c.67_92del p.E23Qfs*54 | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- NID1 | c.3392A>T p.N1131I | Missense Mutation (SNP) | VAF 5/150 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- NKX2-2 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PCSK5 | c.3141G>T p.L1047F | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PRG4 | c.3641C>G p.S1214C | Missense Mutation (SNP) | VAF 31/343 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PTP4A2 | c.-593-2A>G | Splice Site (SNP) | VAF 115/228 reads (50%) | called by muse, mutect2, varscan2
- RAB6D | c.278A>C p.Y93S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RUBCNL | c.1190A>C p.K397T | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TXNDC11 | c.1274C>A p.A425D (on ENST00000356957 / NM_001303447.2; = p.A398D on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- VCP | c.1807C>A p.Q603K | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR7 | c.1874C>G p.A625G | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- XPNPEP2 | c.358_359insT p.Q120Lfs*3 | Frame Shift Ins (INS) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- YEATS2 | c.2767A>C p.K923Q | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ZNF721 | c.2391T>A p.F797L (on ENST00000338977; = p.F809L on NM_133474.4) | Missense Mutation (SNP) | VAF 96/98 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CENPJ | c.1485C>T p.V495= | Silent (SNP) | VAF 31/124 reads (25%) | called by muse, mutect2, varscan2
- DEPDC1 | c.1156A>C p.R386= | Silent (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- DNAH6 | c.3906C>T p.D1302= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs769444078; called by muse, mutect2, varscan2
- HES7 | c.153G>A p.P51= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs1180587901; called by muse, mutect2, varscan2
- IGHV2-70 | c.75G>A p.E25= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as rs181122105; called by muse, varscan2
- IGHV3-20 | c.42A>G p.L14= | Silent (SNP) | VAF 48/50 reads (96%) | catalogued as rs782349083; called by muse, mutect2
- OR10G7 | c.486T>A p.T162= | Silent (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- OR2A14 | c.132C>T p.I44= | Silent (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- SKOR2 | c.33C>T p.D11= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as rs1391433313; called by muse, mutect2, varscan2
- SLC6A15 | c.603T>G p.S201= | Silent (SNP) | VAF 81/182 reads (45%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1603C>T p.L535= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- WDR90 | c.2715G>A p.S905= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs376123449; called by muse, mutect2, varscan2
- AEN | c.*1482G>C | 3'UTR (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- AMBRA1 | c.2421-78G>A | Intron (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- AMOT | c.*3307del | 3'UTR (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65499163 A>G | 5'Flank (SNP) | VAF 11/29 reads (38%) | catalogued as rs879025593; called by muse, varscan2
- AP000769.5 | chr11:65499265 T>C | 5'Flank (SNP) | VAF 34/68 reads (50%) | catalogued as rs534838156; called by muse, varscan2
- AP3B2 | c.360+1701T>G | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- ASH1L | chr1:155563260 G>A | 5'Flank (SNP) | VAF 46/194 reads (24%) | catalogued as rs1292258145; called by muse, mutect2, varscan2
- ATP8A2 | c.*5288C>T | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021245 G>A | 5'Flank (SNP) | VAF 73/147 reads (50%) | catalogued as COSV55851570; called by muse, mutect2, varscan2
- BTBD9 | c.*4425G>A | 3'UTR (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- CACNA1C | chr12:2053389 T>A | 5'Flank (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- CCDC85C | c.*2649G>A | 3'UTR (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- CENPF | c.*418C>T | 3'UTR (SNP) | VAF 104/250 reads (42%) | called by muse, mutect2, varscan2
- DENND1B | c.*5364dup | 3'UTR (INS) | VAF 27/129 reads (21%) | called by mutect2, pindel, varscan2
- DIPK2A | c.-29C>T | 5'UTR (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- DLX6 | c.437-199C>T | Intron (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- DMRTB1 | c.*431A>T | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- ERICH3 | c.-34A>G | 5'UTR (SNP) | VAF 38/39 reads (97%) | called by muse, mutect2, varscan2
- FBXO3 | c.1240-1444T>A | Intron (SNP) | VAF 117/241 reads (49%) | catalogued as rs1436693008; called by muse, mutect2, varscan2
- FEN1 | c.*454G>A | 3'UTR (SNP) | VAF 76/148 reads (51%) | catalogued as rs1354177186; called by muse, mutect2, varscan2
- FREM2 | c.*431G>A | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- GALNT15 | c.*768A>C | 3'UTR (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- GPR158 | c.*2555T>A | 3'UTR (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2, varscan2
- GRIK4 | c.-20T>G | 5'UTR (SNP) | VAF 56/135 reads (41%) | called by muse, mutect2, varscan2
- GSDMD | c.411-157C>T | Intron (SNP) | VAF 51/101 reads (50%) | catalogued as rs1429894859; called by muse, mutect2, varscan2
- HOXD10 | c.*658T>C | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- IGLC3 | c.*42A>T | 3'UTR (SNP) | VAF 68/138 reads (49%) | called by muse, mutect2, varscan2
- IGSF22 | c.2096-1510A>C | Intron (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- KCTD12 | c.*2646C>T | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- LTB | c.163-119G>T | Intron (SNP) | VAF 120/268 reads (45%) | catalogued as COSV53000283, COSV53001753; called by muse, mutect2, varscan2
- MLLT6 | c.*2965C>G | 3'UTR (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- MN1 | c.*2454del | 3'UTR (DEL) | VAF 28/156 reads (18%) | called by mutect2, pindel, varscan2
- MPZL3 | c.*358C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1332202112; called by muse, mutect2, varscan2
- MRAP2 | c.*657A>G | 3'UTR (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54723T>C | Intron (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- PASK | c.*11C>T | 3'UTR (SNP) | VAF 133/296 reads (45%) | called by muse, mutect2, varscan2
- PAXIP1 | chr7:155002975 C>T | 5'Flank (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- PLEC | c.524-703G>C | Intron (SNP) | VAF 5/155 reads (3%) | called by muse, mutect2
- PTPRN2 | c.2344+3871A>T | Intron (SNP) | VAF 8/86 reads (9%) | called by mutect2, varscan2
- RABGEF1 | chr7:66810950 A>T | 3'Flank (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- RARB | chr3:25597061 G>A | 3'Flank (SNP) | VAF 79/152 reads (52%) | catalogued as rs935111817; called by muse, mutect2, varscan2
- RNF152 | c.*2436del | 3'UTR (DEL) | VAF 47/81 reads (58%) | catalogued as rs944588011; called by mutect2, varscan2
- RUNX1 | c.724+13127C>A | Intron (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- SOX11 | c.*494C>A | 3'UTR (SNP) | VAF 30/51 reads (59%) | catalogued as rs1056961081, COSV58984915; called by muse, mutect2, varscan2
- SOX17 | c.*830C>A | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- SOX21 | c.*66C>T | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- SSR1 | c.*3664T>A | 3'UTR (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- TMEM170A | c.*2704T>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- TNKS | c.*1195G>A | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- TPT1 | c.-80G>A | 5'UTR (SNP) | VAF 78/99 reads (79%) | called by muse, mutect2, varscan2
- TRIOBP | c.6324+886G>C | Intron (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2
- TXNDC5 | c.*829C>G | 3'UTR (SNP) | VAF 8/132 reads (6%) | catalogued as rs1251796575; called by muse, mutect2
- UBN2 | c.*941C>T | 3'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- UVRAG | c.-74T>G | 5'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- VIPR2 | c.*1719G>T | 3'UTR (SNP) | VAF 186/443 reads (42%) | catalogued as rs1484383397; called by muse, mutect2, varscan2
- VPS13D | c.*2807G>A | 3'UTR (SNP) | VAF 60/119 reads (50%) | catalogued as rs939976786; called by muse, mutect2, varscan2
- WDFY1 | c.*1246C>T | 3'UTR (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- WDR41 | c.*1683C>G | 3'UTR (SNP) | VAF 37/99 reads (37%) | called by muse, mutect2, varscan2
- Z98752.3 | c.201+9187C>A | Intron (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.*296C>T | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- ZNF140 | c.10-596T>G | Intron (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- ZNF277 | c.293+1103G>A | Intron (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- ZNF598 | c.1292+13G>T | Intron (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- ZNF681 | c.*4299G>A | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.588+3931A>C | Intron (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
